Surgical pathology report (de-identified scan), TCGA case TCGA-A2-A0D1, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Walter Reed, specimen TCGA-A2-A0D1-01A (Primary Tumor).

[page 1 of 3]
UUID:SDFA7970-3F68-4FC3-B2BA-5A42E866ECC3

NLY - PERSONAL DATA - PRIVACY ACT OF 1974

SURGICAL PATHOLOGY REPORT

Patient:
FMP/SSN:
DOB/Age/Sex:
Location:
Physician(s):

♂ Race: WHITE

Specimen #:

Taken:
Received:
Reported:

****AMENDED****

108-0-3

Carcinoma, infiltrating ductal, no.
8500/3

Site: breast, NOS C50.9

1/25/11 W

SPECIMEN:

- A: SENTINEL NODE #1 B: ADDITIONAL LYMPH NODE
C: SENTINEL LYMPH NODE #2 D: LEFT BREAST LUMPECTOMY
E: FIBROUS TISSUE AT SUP-LAT MARGIN

FINAL DIAGNOSIS:

- A. LYMPH NODE, SENTINEL #1, EXCISION:
- TWO BENIGN LYMPH NODES, NO MALIGNANCY IDENTIFIED.
- B. LYMPH NODE, "ADDITIONAL," EXCISION:
- NO LYMPH NODE IDENTIFIED. FIBROADIPOSE TISSUE ONLY.
- C. LYMPH NODE, SENTINEL #2, EXCISION:
- ONE BENIGN LYMPH NODE, NO MALIGNANCY IDENTIFIED.
- D. BREAST, LEFT, LUMPECTOMY:
TUMOR TYPE: INFILTRATING DUCTAL CARCINOMA WITH NEUROENDOCRINE FEATURES.
NOTTINGHAM GRADE: POORLY DIFFERENTIATED (G3).
NOTTINGHAM SCORE: 8/9
(Tubules= 3, Nuclei= 3, Mitoses= 2; mitotic count 8 per 10 HPF at 20x power-0.50 field diameter)
TUMOR SIZE (GREATEST DIMENSION): 3.0 CM (measured grossly)
TUMOR NECROSIS: ABSENT.
MICROCALCIFICATIONS: ABSENT.
VENOUS / LYMPHATIC INVASION: NOT IDENTIFIED.
MARGINS:
-DISTANCE OF INVASIVE TUMOR FROM NEAREST MARGIN IS 0.5 CM, FROM INFERIOR MARGIN.
INTRADUCTAL COMPONENT: DUCTAL CARCINOMA IN SITU, SOLID TYPE, LOW NUCLEAR GRADE.
LYMPH NODES: THREE NEGATIVE FOR TUMOR (see specimens A and C)
MULTICENTRICITY: NOT IDENTIFIED.
ESTROGEN RECEPTORS: NEGATIVE. (see specimen
PROGESTERONE RECEPTORS: NEGATIVE. (see specimen
HER 2 NEU by IHC: POSITIVE. (see specimen

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

Patient:

Specimen #:

FINAL DIAGNOSIS (continued):

PATHOLOGIC STAGE: pT2 N0 Mx

ADDITIONAL PATHOLOGIC CHANGES: BENIGN INTRADUCTAL PAPILLOMA.

E. SOFT TISSUE, "FIBROUSE TISSUE AT SUPERIOR-LATERAL MARGIN," EXCISION:
- BENIGN BREAST TISSUE, NO MALIGNANCY IDENTIFIED.

** Report Electronically Signed Out **

=====

CLINICAL DIAGNOSIS AND HISTORY:

-year-old female with diagnosis of left breast cancer.

GROSS DESCRIPTION:

A. Received fresh, labeled with the patient's name, designated "SENTINEL NODE #1" is a 3.0 x 1.5 x 0.5 cm irregular portion of soft tissue. Sectioning reveals a 1.0 x 1.0 x 0.5 cm pink-tan lymph node. The lymph node is bisected. One half of the lymph node is submitted in OCT for CBCP protocol, and the remainder is submitted for permanent. 2C2

B. Received in formalin, labeled with the patient's name, designated "ADDITIONAL LYMPH NODE" is a single, tan-brown fragment of soft tissue measuring 1.0 cm in greatest dimension. The specimen is submitted in its entirety in one cassette. 1C1

C. Received in formalin, labeled with the patient's name, designated "SENTINEL LYMPH NODE #2" is a lobulated fragment of yellow, adipose tissue measuring 1.5 x 2.0 x 0.3 cm. The specimen is bisected to reveal one lymph node measuring 0.7 cm in greatest dimension. The specimen is submitted entirely in one cassette. 1C2

D. Received fresh, labeled with the patient's name, designated "LEFT BREAST LUMPECTOMY" is a globoid portion of soft tissue oriented with the short stitch superior and long stitch lateral. The specimen measures 9.0 cm medial to lateral, 7.5 cm anterior to posterior, and 4.0 cm superior to inferior. The lightly pigmented superficial skin ellipse measures 6.5 x 1.0 cm and is otherwise unremarkable. The specimen is inked as follows: superior = gold, inferior = green, medial = red, lateral = yellow, anterior = orange, and posterior = black. Serial

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

Patient:

Specimen #:

GROSS DESCRIPTION (continued):

sections reveal a firm, very well circumscribed, centrally located, pink-white mass measuring 3.0 x 2.6 x 2.2 cm. The mass approaches the margins as follows: superior and inferior 0.7 cm, posterior 0.8 cm, and medial 1.4 cm. The remainder of the cut surface is composed of lobulated, yellow-tan, adipose tissue admixed with a moderate amount of tan-white, fibrous tissue. No additional lesions are identified. Representative sections are submitted as follows:

Cassette Summary:

- D1-D2: Mass.
- D3: Adjacent normal.
- D4-D5: Additional mass.
- D6-D7: Adjacent to mass.
- D8: Additional mass, same section as D4.
- D9: Skin.
- D10: Additional firm, fibrous tissue. 10CF

The specimen was placed in formalin at formalin for a total of approximately 28 hours. The specimen will be in

E. Received in formalin, labeled with the patient's name, designated "FIBROUS TISSUE AT SUPERIOR-LATERAL MARGIN" is a fragment of yellow-white, fibrous tissue and adipose tissue measuring 3.7 x 2.0 x 0.8 cm. Representative sections are submitted entirely in three cassettes. 3C3

Reviewer Initials	Date Review: 11/20/10	

Source: NCI Genomic Data Commons file 961d08bb-6aac-412a-a935-cadd564f6a30 (TCGA-A2-A0D1.5DFA7970-3F68-4FC3-B2BA-5A42E866ECC3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).